Somatic mutation profile of tumor specimen TCGA-GN-A8LK-06A (aliquot TCGA-GN-A8LK-06A-11D-A372-08) from TCGA case TCGA-GN-A8LK, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.4 years (26,808 days).
Specimen TCGA-GN-A8LK-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a61e50e-6a37-46eb-8864-a2f276b63084.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A8LK-10A (Blood Derived Normal), aliquot TCGA-GN-A8LK-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77af0fde-6cf6-43f9-81e4-0072fa296958

The open-access MAF lists 2,397 somatic variants for this specimen: 1,580 protein-altering or splice-affecting, 764 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,421, Silent 764, Nonsense Mutation 94, Splice Site 23, Splice Region 17, Intron 16, RNA 16, Frame Shift Del 10, 5'Flank 8, In Frame Del 8, 3'UTR 7, Translation Start Site 4.

Variants (750 of 2,397; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2107del p.A703Qfs*15 | Frame Shift Del (DEL) | VAF 46/68 reads (68%) | catalogued as rs587783030; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL3A1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs1333421028, COSV100482209; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAFAH1B1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 27/48 reads (56%) | catalogued as rs121434483, CM971120, COSV101250297; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNR | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs892080402, COSV54899846, COSV54900270; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1195C>T p.R399C (on ENST00000373993 / NM_138932.2; = p.R391C on NM_014576.4) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs766706018, COSV99254982; called by muse, mutect2, varscan2
- A1CF | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs769626580, COSV99254986; called by muse, mutect2, varscan2
- AARD | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV65599903; called by muse, mutect2, varscan2
- ABCA10 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.308); catalogued as rs202012056; called by muse, mutect2, varscan2
- ABCA6 | c.3696C>T p.F1232= | Splice Region (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99445485; called by muse, mutect2, varscan2
- ABCB4 | c.3448G>A p.E1150K (on ENST00000265723 / NM_018849.3; = p.E1143K on NM_000443.4) | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV99709492; called by muse, mutect2, varscan2
- ABCB5 | c.3538G>A p.D1180N (on ENST00000404938 / NM_001163941.2; = p.D735N on NM_178559.6) | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99327096; called by muse, mutect2, varscan2
- ABCC1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 117/283 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs775155522, COSV60680588; called by muse, mutect2, varscan2
- ABCC12 | c.1237-1G>A p.X413_splice | Splice Site (SNP) | VAF 55/62 reads (89%) | catalogued as COSV100252021; called by muse, mutect2, varscan2
- AC008676.3 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV100400321; called by muse, mutect2, varscan2
- AC097636.1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs377591770; called by muse, mutect2, varscan2
- AC098582.1 | c.1427C>A p.S476Y | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as rs1319143474, COSV99985170; called by muse, mutect2, varscan2
- AC126283.2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101143985; called by muse, mutect2, varscan2
- ACAD11 | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.4); catalogued as rs1559965451, COSV99391420; called by muse, mutect2, varscan2
- ACADL | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.046); catalogued as COSV52053093; called by muse, mutect2, varscan2
- ACMSD | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977255757, COSV51606228; called by muse, mutect2, varscan2
- ACO2 | c.2147A>G p.N716S | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1192448800, COSV99346925; called by muse, mutect2, varscan2
- ACP3 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs760000878, COSV100313043; called by muse, mutect2, varscan2
- ACP7 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100488391; called by muse, mutect2, varscan2
- ACSBG1 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99356906; called by muse, mutect2, varscan2
- ACSL6 | c.1310C>T p.P437L (on ENST00000379240; = p.P462L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57299445; called by muse, mutect2, varscan2
- ACSM2A | c.1186G>A p.D396N (on ENST00000219054; = p.D317N on NM_001308169.2) | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV54583345, COSV54587238; called by muse, mutect2, varscan2
- ACTN1 | c.1889G>A p.R630K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99517017; called by muse, mutect2, varscan2
- ACTR5 | c.1318C>T p.H440Y | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.625); catalogued as COSV54762211; called by muse, mutect2, varscan2
- ADAM18 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99694630; called by muse, mutect2, varscan2
- ADAM18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs267601916, COSV55844457; called by muse, mutect2, varscan2
- ADAM19 | c.2398G>A p.G800S | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1384140225, COSV99975742; called by muse, mutect2, varscan2
- ADAM23 | c.2155A>T p.M719L | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100006322; called by muse, mutect2, varscan2
- ADAM32 | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1013358998, COSV101165182; called by muse, mutect2, varscan2
- ADAM33 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1232973480, COSV100597636; called by muse, mutect2
- ADAM7 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.66); PolyPhen probably damaging (1); catalogued as COSV99442740; called by muse, mutect2, varscan2
- ADAM7 | c.1108T>G p.F370V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99442743; called by muse, mutect2, varscan2
- ADAMTS12 | c.3965G>A p.W1322* | Nonsense Mutation (SNP) | VAF 80/82 reads (98%) | catalogued as COSV100710083; called by muse, mutect2, varscan2
- ADAMTS18 | c.3437G>A p.R1146Q | Missense Mutation (SNP) | VAF 59/61 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374530203, COSV99270838; called by muse, mutect2, varscan2
- ADAMTS2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as rs763890617, COSV99200985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.3914G>A p.G1305E | Missense Mutation (SNP) | VAF 96/112 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as COSV67137280; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1271433762; called by muse, mutect2, varscan2
- ADARB1 | c.1969G>A p.G657R (on ENST00000360697 / NM_001346687.2; = p.G617R on NM_001112.4) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569188089, COSV100653558; called by muse, mutect2, varscan2
- ADCY4 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as rs1208042568, COSV100156051; called by muse, mutect2
- ADGRB3 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as COSV100999516, COSV65418202; called by muse, mutect2, varscan2
- ADGRL2 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 67/77 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99586688; called by muse, mutect2, varscan2
- ADGRL3 | c.2418T>C p.N806= (on ENST00000506720 / NM_001322402.2; = p.N738= on NM_015236.6) | Splice Region (SNP) | VAF 9/10 reads (90%) | catalogued as COSV101546768; called by muse, mutect2, varscan2
- ADGRL4 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs770487483, COSV100875487; called by muse, mutect2, varscan2
- ADGRV1 | c.2876C>T p.T959I | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV101315306; called by muse, mutect2, varscan2
- ADGRV1 | c.8488C>T p.L2830F | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV101315308; called by muse, mutect2, varscan2
- ADH1C | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV101565154; called by muse, mutect2, varscan2
- ADIPOR2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1321520886, COSV100840004; called by muse, mutect2, varscan2
- ADRA2A | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.067); catalogued as COSV99701395; called by muse, mutect2, varscan2
- AFDN | c.3824C>T p.S1275F | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs771734580, COSV100653214, COSV60045084; called by muse, mutect2, varscan2
- AFM | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs1163878650, COSV99888355; called by muse, mutect2, varscan2
- AGAP2 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV99221980; called by muse, mutect2
- AGAP6 | c.1472C>T p.S491F (on ENST00000374056 / NM_001365867.1; = p.S514F on NM_001077665.2) | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554865248, COSV100929015; called by muse, mutect2, varscan2
- AGBL1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1318937752, COSV66863378; called by muse, mutect2, varscan2
- AGFG2 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as COSV99499078; called by muse, mutect2, varscan2
- AHNAK2 | c.7348G>A p.E2450K | Missense Mutation (SNP) | VAF 200/209 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100315033, COSV100315266; called by muse, mutect2, varscan2
- AJM1 | c.2306G>A p.G769D | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237079283, COSV99915317; called by muse, mutect2, varscan2
- AKR1B10 | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 104/224 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs1240363170, COSV100610117; called by muse, mutect2, varscan2
- AKR1C2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1554773538, COSV101060363; called by muse, mutect2, varscan2
- AKR1D1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs146708783, COSV54341545; called by muse, mutect2, varscan2
- ALB | c.1301G>C p.R434P | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55738615, COSV99890464; called by muse, mutect2, varscan2
- ALDH1A2 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 197/679 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV99990179; called by muse, mutect2, varscan2
- ALDOB | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 175/279 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100878797; called by muse, mutect2, varscan2
- ALKBH1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV99380393; called by muse, mutect2, varscan2
- ALMS1 | c.4082C>T p.S1361L | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV100040812; called by muse, mutect2, varscan2
- ALMS1 | c.4694C>T p.T1565I | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV100040815; called by muse, mutect2, varscan2
- ALPK2 | c.3154C>T p.P1052S | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as COSV64495438; called by muse, mutect2, varscan2
- ALPK2 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV64494350; called by muse, mutect2, varscan2
- AMY2A | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV101340610; called by muse, mutect2, varscan2
- ANK2 | c.10046C>T p.P3349L | Missense Mutation (SNP) | VAF 82/86 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100003248, COSV52180948; called by muse, mutect2, varscan2
- ANK3 | c.10471C>T p.P3491S | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99777690; called by muse, mutect2, varscan2
- ANK3 | c.9223G>A p.E3075K | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV99777691; called by muse, mutect2, varscan2
- ANK3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99777692; called by muse, mutect2, varscan2
- ANKLE1 | c.1300A>C p.I434L (on ENST00000394458; = p.I380L on NM_152363.6) | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100845688; called by muse, mutect2, varscan2
- ANKLE2 | c.2216T>G p.L739R | Missense Mutation (SNP) | VAF 96/162 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100513869; called by muse, mutect2, varscan2
- ANKRD30A | c.1000G>A p.G334R (on ENST00000611781; = p.G278R on NM_052997.2) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV100652654; called by muse, mutect2, varscan2
- ANKRD30A | c.3189A>C p.L1063F (on ENST00000611781; = p.L1007F on NM_052997.2) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV100652655; called by muse, mutect2, varscan2
- ANKS1B | c.2851C>T p.P951S (on ENST00000547776 / NM_152788.4; = p.P177S on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs778854237, COSV100226867; called by muse, varscan2
- ANKS1B | c.2339G>A p.W780* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100242057; called by muse, mutect2, varscan2
- ANO2 | c.1929G>A p.G643= (on ENST00000356134 / NM_001278597.3; = p.G647= on NM_001278596.3) | Splice Region (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100499406; called by muse, mutect2, varscan2
- ANO2 | c.751C>T p.P251S (on ENST00000356134 / NM_001278597.3; = p.P255S on NM_001278596.3) | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as rs753346613, COSV100499410; called by muse, mutect2, varscan2
- ANO9 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV100240706; called by muse, mutect2, varscan2
- ANP32E | c.681G>A p.Q227= | Splice Region (SNP) | VAF 145/223 reads (65%) | catalogued as COSV100029525; called by muse, mutect2, varscan2
- AOAH | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99331832; called by muse, mutect2, varscan2
- AOX1 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV65980051; called by muse, mutect2, varscan2
- AP2A2 | c.2242A>T p.T748S | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100172343; called by muse, mutect2, varscan2
- APAF1 | c.2791C>T p.Q931* (on ENST00000551964 / NM_181861.2; = p.Q877* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV100452215; called by muse, mutect2, varscan2
- APC | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV99964416; called by muse, mutect2, varscan2
- APOB | c.2521G>A p.G841R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262939; called by muse, mutect2, varscan2
- APOH | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99235459; called by muse, mutect2, varscan2
- APOL1 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.814); catalogued as COSV100045858; called by muse, varscan2
- ARGLU1 | c.361A>T p.I121L | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.658); catalogued as COSV100639735; called by muse, mutect2, varscan2
- ARHGAP15 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1177528659, COSV99707629; called by muse, mutect2, varscan2
- ARHGAP25 | c.1413G>C p.W471C (on ENST00000409202 / NM_001007231.3; = p.W463C on NM_014882.3) | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV99770831; called by muse, mutect2, varscan2
- ARHGEF11 | c.2878G>A p.D960N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100168133, COSV59355109; called by muse, mutect2, varscan2
- ARHGEF15 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as COSV100729963; called by muse, mutect2, varscan2
- ARHGEF35 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100967659; called by muse, mutect2, varscan2
- ARHGEF5 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769482772, COSV99282465, COSV99282618; called by mutect2, varscan2
- ARID4B | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99934788; called by muse, mutect2, varscan2
- ARIH2 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV62704064; called by muse, mutect2, varscan2
- ARMC12 | c.541G>A p.D181N (on ENST00000373866 / NM_001286574.2; = p.D208N on NM_145028.5) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); catalogued as rs146354524; called by muse, mutect2, varscan2
- ARMH4 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99957442; called by muse, mutect2, varscan2
- ARSG | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101477863; called by muse, mutect2, varscan2
- ARSH | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101139708; called by muse, mutect2, varscan2
- ASIC3 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs750380438, COSV52501799; called by muse, mutect2, varscan2
- ASTN1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763391667, COSV56064196; called by muse, mutect2, varscan2
- ASTN2 | c.1331C>T p.S444F (on ENST00000313400 / NM_001365069.1; = p.S393F on NM_014010.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs866109686, COSV57764562; called by muse, mutect2, varscan2
- ASXL3 | c.6455G>A p.G2152E | Missense Mutation (SNP) | VAF 96/112 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99322821; called by muse, mutect2, varscan2
- ATF6B | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV64351961; called by muse, mutect2, varscan2
- ATP10B | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.242); catalogued as COSV100513878, COSV99046166; called by muse, mutect2, varscan2
- ATP10B | c.2416+1G>A p.X806_splice | Splice Site (SNP) | VAF 33/76 reads (43%) | catalogued as rs771447401, COSV100513881, COSV59153325; called by muse, mutect2, varscan2
- ATP13A2 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV100453818; called by muse, mutect2, varscan2
- ATP13A4 | c.2509C>T p.Q837* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | catalogued as COSV61328432; called by muse, mutect2, varscan2
- ATP1A3 | c.1138A>G p.K380E (on ENST00000545399 / NM_001256214.2; = p.K367E on NM_152296.5) | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131794; called by muse, mutect2, varscan2
- ATP2B2 | c.1720G>A p.E574K (on ENST00000352432; = p.E540K on NM_001683.5) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs764853768, COSV59505006; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2134C>T p.H712Y | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100376762; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2444A>G p.N815S | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.751); catalogued as COSV100022437; called by muse, mutect2, varscan2
- ATP6V0D2 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.583); catalogued as COSV99571188; called by muse, mutect2, varscan2
- ATP8A1 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758452932, COSV100044576; called by muse, mutect2, varscan2
- ATP8A2 | c.2303C>T p.T768I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54976080, COSV99679352; called by muse, mutect2, varscan2
- ATRNL1 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1554924632, COSV58101757; called by muse, mutect2, varscan2
- ATRNL1 | c.3028C>T p.Q1010* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as COSV58090104; called by muse, mutect2, varscan2
- ATXN1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867470111, COSV55222946; called by muse, mutect2, varscan2
- AUP1 | c.189-1G>A p.X63_splice | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as COSV99239378; called by muse, mutect2, varscan2
- B3GNT8 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54196306, COSV54197815; called by muse, mutect2, varscan2
- BAG6 | c.2659T>C p.F887L (on ENST00000676571; = p.F840L on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.098); catalogued as COSV99276217; called by muse, mutect2, varscan2
- BAHCC1 | c.3757C>T p.P1253S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1555654887, COSV57032016; called by muse, mutect2, varscan2
- BAIAP3 | c.3487G>A p.G1163S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as rs140483333, COSV50105249; called by muse, mutect2, varscan2
- BAIAP3 | c.3488G>A p.G1163D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs746622792, COSV99136095; called by muse, mutect2, varscan2
- BCAR3 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 73/78 reads (94%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as rs753513831, COSV99550033; called by muse, mutect2, varscan2
- BCL2L12 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.221); catalogued as COSV99880787; called by muse, mutect2, varscan2
- BCL2L12 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV55863847; called by muse, mutect2, varscan2
- BCL2L12 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs754342318, COSV99880791; called by muse, varscan2
- BEND4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.16); catalogued as rs771898046, COSV72468916, COSV72469273; called by muse, mutect2, varscan2
- BICC1 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.265); catalogued as COSV99570051, COSV99570741; called by muse, mutect2, varscan2
- BNIP5 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1389706720, COSV101465096; called by muse, mutect2, varscan2
- BOD1L1 | c.7381G>A p.E2461K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.109); catalogued as COSV99238109; called by muse, mutect2, varscan2
- BPGM | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100790145; called by muse, mutect2, varscan2
- BPIFB4 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100971382; called by muse, mutect2, varscan2
- BRDT | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100746040, COSV62865393; called by muse, mutect2, varscan2
- BRINP3 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs773859506, COSV66531362; called by muse, mutect2, varscan2
- BRPF3 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV60206467; called by muse, mutect2, varscan2
- BRSK1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100473521; called by muse, mutect2, varscan2
- BSPRY | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs762277492, COSV99444728; called by muse, mutect2, varscan2
- BTBD11 | c.1859T>C p.V620A (on ENST00000280758 / NM_001018072.2; = p.V157A on NM_001017523.2) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1229425563, COSV99774481; called by muse, mutect2, varscan2
- BTN3A1 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV50025286; called by muse, mutect2, varscan2
- C12orf42 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1354629031, COSV59382911; called by muse, mutect2, varscan2
- C12orf50 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs757520062, COSV53898848; called by muse, mutect2, varscan2
- C1QA | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101009947; called by muse, mutect2, varscan2
- C1orf87 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 121/122 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs777167217, COSV100966874; called by muse, mutect2, varscan2
- C1orf94 | c.1621C>T p.P541S (on ENST00000488417 / NM_001134734.2; = p.P351S on NM_032884.5) | Missense Mutation (SNP) | VAF 58/60 reads (97%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV64913054; called by muse, mutect2, varscan2
- C2orf78 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV68517970; called by muse, mutect2, varscan2
- C3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV55571762; called by muse, mutect2, varscan2
- C3orf52 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV99332213; called by muse, mutect2, varscan2
- C5 | c.3629C>T p.S1210L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV99796916; called by muse, mutect2, varscan2
- C6orf118 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs149970829; called by muse, mutect2, varscan2
- C7orf61 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV55725076; called by muse, mutect2, varscan2
- C9 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54680767; called by muse, mutect2, varscan2
- CA10 | c.554T>C p.F185S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99561026; called by muse, mutect2, varscan2
- CA10 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 185/352 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs267604958, COSV53362047, COSV53371994; called by muse, mutect2, varscan2
- CA9 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.529); catalogued as rs536591247, COSV100999749; called by muse, mutect2, varscan2
- CABP2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99590679; called by muse, mutect2, varscan2
- CACNA1C | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs762162937, COSV59778777; called by muse, varscan2
- CACNA1E | c.3083G>A p.G1028D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.056); catalogued as COSV100701156; called by muse, mutect2, varscan2
- CACNA1E | c.4874G>A p.G1625E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100701157; called by muse, mutect2, varscan2
- CACNA1I | c.4283G>A p.G1428D | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV100358907; called by muse, mutect2, varscan2
- CACNA2D3 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.903); catalogued as rs753921913, COSV55513596; called by muse, mutect2, varscan2
- CACNA2D3 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 117/212 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV55564663; called by muse, varscan2
- CACNA2D3 | c.2690G>A p.R897K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99868467; called by muse, mutect2
- CACNB4 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.038); catalogued as rs1169898698, CM086705, COSV99137682; called by muse, mutect2, varscan2
- CADM1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV100521998, COSV100522638; called by muse, mutect2, varscan2
- CADM1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100521999; called by muse, mutect2, varscan2
- CALB2 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1247948888, COSV56938258; called by muse, mutect2, varscan2
- CALY | c.246G>A p.R82= | Splice Region (SNP) | VAF 7/19 reads (37%) | catalogued as rs1158342708, COSV99428555; called by muse, mutect2, varscan2
- CALY | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99428559; called by muse, varscan2
- CAMSAP1 | c.3898G>T p.E1300* | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100409491; called by muse, mutect2, varscan2
- CAPN13 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs946319949, COSV99699577; called by muse, mutect2, varscan2
- CARD11 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs753205129, COSV100829061; called by muse, mutect2, varscan2
- CARMIL1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100276590; called by muse, mutect2, varscan2
- CARMIL1 | c.3475G>A p.G1159R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100276592; called by muse, mutect2, varscan2
- CARMIL1 | c.3476G>A p.G1159E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100276594; called by muse, mutect2, varscan2
- CARMIL2 | c.3775C>T p.P1259S | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99537319; called by muse, mutect2, varscan2
- CASP14 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as rs775612358, COSV55666308; called by muse, mutect2, varscan2
- CASR | c.2764G>A p.E922K (on ENST00000490131; = p.E999K on NM_000388.4) | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99948333; called by muse, mutect2, varscan2
- CBX6 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99327913; called by muse, mutect2, varscan2
- CBX8 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99485691; called by muse, mutect2, varscan2
- CBX8 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs143582959, COSV99485696; called by muse, mutect2, varscan2
- CC2D2A | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as rs745699870, COSV101052624; called by muse, mutect2, varscan2
- CCAR1 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.833); catalogued as rs752182150, COSV99770447; called by muse, mutect2, varscan2
- CCDC138 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99718652; called by muse, mutect2, varscan2
- CCDC144A | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.093); catalogued as COSV100138236; called by muse, mutect2, varscan2
- CCDC144A | c.3220C>T p.Q1074* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100138237; called by mutect2, varscan2
- CCDC144A | c.3639A>T p.K1213N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV100138238; called by muse, mutect2, varscan2
- CCDC170 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99498032; called by muse, mutect2, varscan2
- CCDC42 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs778525153, COSV99549621, COSV99549785; called by muse, mutect2, varscan2
- CCDC83 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 62/137 reads (45%) | catalogued as COSV99721393; called by muse, mutect2, varscan2
- CCDC88A | c.3214C>T p.L1072F | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99709565; called by muse, mutect2, varscan2
- CCER1 | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100726911; called by muse, mutect2, varscan2
- CCL1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99861646; called by muse, mutect2, varscan2
- CCNT2 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99749958; called by muse, mutect2, varscan2
- CCT6B | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs1438950391, COSV100030352; called by muse, mutect2, varscan2
- CD163 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV100775572; called by muse, mutect2, varscan2
- CD163L1 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs867207568, COSV100549499; called by muse, mutect2, varscan2
- CD163L1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs957319890, COSV100549500, COSV100549904; called by muse, mutect2, varscan2
- CD300LB | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100075262; called by muse, mutect2, varscan2
- CD5L | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100940964; called by muse, mutect2, varscan2
- CD84 | c.928G>A p.E310K (on ENST00000311224 / NM_001184879.2; = p.E293K on NM_003874.4) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV100245748, COSV60868531; called by muse, mutect2, varscan2
- CD8B | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.667); catalogued as COSV100514330; called by muse, mutect2, varscan2
- CD99L2 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100691882; called by muse, mutect2, varscan2
- CDC25B | c.1034C>T p.P345L (on ENST00000245960 / NM_021873.3; = p.P331L on NM_004358.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756602132, COSV99847450; called by muse, varscan2
- CDCP2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 55/58 reads (95%) | SIFT tolerated (0.96); PolyPhen benign (0.026); catalogued as COSV100313240; called by muse, mutect2, varscan2
- CDH23 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs746779432, COSV99818247; called by muse, mutect2, varscan2
- CDH23 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV54943341; called by muse, varscan2
- CDH23 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as rs1407181036, COSV99818261; called by muse, mutect2, varscan2
- CDH6 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54076848, COSV99035111; called by muse, mutect2, varscan2
- CDKL3 | c.627A>T p.L209F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99527454; called by muse, mutect2, varscan2
- CDYL2 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 48/51 reads (94%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1273667185, COSV101629489; called by muse, mutect2, varscan2
- CEACAM3 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.349); catalogued as COSV99704754; called by muse, mutect2, varscan2
- CEL | c.2213C>T p.P738L (on ENST00000673714; = p.P735L on NM_001807.6) | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100672160; called by muse, mutect2, varscan2
- CELSR1 | c.8701C>T p.R2901C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs541572721, COSV99416350; called by muse, mutect2, varscan2
- CELSR2 | c.5522C>T p.S1841F | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99602813; called by muse, mutect2, varscan2
- CEMIP2 | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs571284402, COSV100987191; called by muse, mutect2, varscan2
- CENPE | c.3842A>C p.E1281A | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99476710; called by muse, mutect2, varscan2
- CENPJ | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV101121443; called by muse, mutect2, varscan2
- CENPN | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100001031, COSV100001203; called by muse, mutect2, varscan2
- CEP135 | c.2797C>T p.Q933* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as COSV57259960, COSV57260710; called by muse, mutect2, varscan2
- CEP152 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 63/69 reads (91%) | SIFT tolerated (0.89); PolyPhen benign (0.099); catalogued as rs1165914181, COSV100358383; called by muse, mutect2, varscan2
- CEP41 | c.935A>C p.Y312S | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV56218492, COSV99782490; called by muse, mutect2, varscan2
- CEP70 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs766941120, COSV99388708; called by muse, mutect2, varscan2
- CERS3 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 74/112 reads (66%) | SIFT tolerated (0.79); PolyPhen benign (0.254); catalogued as rs771126884, COSV99430898; called by muse, mutect2, varscan2
- CES1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62085963; called by muse, mutect2, varscan2
- CFAP20DC | c.547G>C p.D183H (on ENST00000482387 / NM_001351530.2; = p.D58H on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99917834; called by muse, mutect2, varscan2
- CFAP43 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV99530268; called by muse, mutect2, varscan2
- CFAP92 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as COSV99414504; called by muse, mutect2, varscan2
- CFL1 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100353955; called by muse, mutect2, varscan2
- CGNL1 | c.3487G>T p.E1163* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as rs1313217743, COSV99847185; called by muse, mutect2, varscan2
- CHAT | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60322756; called by muse, mutect2, varscan2
- CHD1L | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 156/257 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63614303, COSV63614925; called by muse, mutect2, varscan2
- CHD1L | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 159/261 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100787270; called by muse, mutect2, varscan2
- CHD5 | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312036; called by muse, mutect2, varscan2
- CHGA | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs1182582443, COSV53662744, COSV99380964; called by muse, mutect2, varscan2
- CHPF2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); catalogued as COSV99222669; called by muse, mutect2, varscan2
- CHPF2 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99222670; called by muse, mutect2, varscan2
- CHPF2 | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1307105529, COSV99222671; called by muse, mutect2, varscan2
- CHRD | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99200220; called by muse, mutect2, varscan2
- CHRM2 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.82); catalogued as COSV100280510, COSV57774866; called by muse, mutect2, varscan2
- CHRM2 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280511; called by muse, mutect2, varscan2
- CHRM3 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1194552689, COSV55098084, COSV99697200; called by muse, mutect2, varscan2
- CHRNA9 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs745654047, COSV59573936; called by muse, mutect2, varscan2
- CHST10 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV99958571, COSV99958602; called by muse, mutect2, varscan2
- CIC | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.174); catalogued as rs200388659, COSV99358705; called by muse, mutect2, varscan2
- CILP2 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342176639, COSV52278716; called by muse, mutect2, varscan2
- CKAP5 | c.3320C>T p.S1107L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99043894; called by muse, mutect2, varscan2
- CLCN3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV61626813; called by muse, mutect2, varscan2
- CLEC9A | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100191021; called by muse, mutect2, varscan2
- CLIC3 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs377369832; called by muse, mutect2, varscan2
- CLIP2 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV56275444; called by muse, mutect2, varscan2
- CLIP2 | c.2410C>T p.Q804* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as rs1554313078, COSV99790831; called by muse, mutect2
- CLPTM1L | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.805); catalogued as COSV100306720; called by muse, mutect2, varscan2
- CLRN1 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 36/114 reads (32%) | catalogued as COSV99902237; called by muse, mutect2, varscan2
- CLU | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs777397743, COSV100324087; called by muse, mutect2, varscan2
- CNGA2 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 72/77 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61703278; called by muse, mutect2, varscan2
- CNGA4 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs754953959, COSV101171709; called by muse, mutect2, varscan2
- CNGB3 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 151/328 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100180996; called by muse, mutect2, varscan2
- CNOT6 | c.1013C>G p.S338W | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.78); catalogued as COSV56164188, COSV56164227, COSV99993357; called by muse, mutect2
- CNOT6 | c.1015A>C p.I339L | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV99993360; called by muse, mutect2
- CNTN4 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV61870303; called by muse, mutect2, varscan2
- CNTN5 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1436874415, COSV54275052, COSV99681181; called by muse, mutect2, varscan2
- CNTN6 | c.2152G>C p.V718L | Missense Mutation (SNP) | VAF 89/165 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV63183796; called by muse, mutect2, varscan2
- CNTNAP2 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs777946931, COSV62162609; called by muse, mutect2, varscan2
- CNTNAP5 | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285313207, COSV101442888, COSV101443256; called by muse, mutect2, varscan2
- COBLL1 | c.2168C>T p.S723L (on ENST00000392717; = p.S685L on NM_014900.5) | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52066097; called by muse, mutect2, varscan2
- COL11A1 | c.4090C>T p.P1364S | Missense Mutation (SNP) | VAF 51/53 reads (96%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as COSV62193617; called by muse, mutect2, varscan2
- COL11A2 | c.3136G>A p.E1046K (on ENST00000341947 / NM_080680.3; = p.E939K on NM_080679.2) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100553295; called by muse, mutect2, varscan2
- COL12A1 | c.4795C>T p.R1599* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV100485159, COSV59401096; called by muse, mutect2, varscan2
- COL15A1 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100897296; called by muse, mutect2, varscan2
- COL15A1 | c.3547C>T p.P1183S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV66649620; called by muse, mutect2, varscan2
- COL1A2 | c.2926G>A p.G976R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483022868, COSV99798122; called by muse, mutect2, varscan2
- COL20A1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as rs772653429, COSV58911706; called by muse, mutect2, varscan2
- COL21A1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs867948640, COSV55159384; called by muse, mutect2, varscan2
- COL21A1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55160911; called by muse, mutect2, varscan2
- COL3A1 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV100482213; called by muse, mutect2, varscan2
- COL4A5 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60370462; called by muse, mutect2, varscan2
- COL4A6 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 138/140 reads (99%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.869); catalogued as COSV57860701; called by muse, mutect2, varscan2
- COL4A6 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 82/86 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1380005535, COSV100563061; called by muse, mutect2, varscan2
- COL5A1 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100879316; called by muse, mutect2, varscan2
- COL5A1 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100879318; called by muse, mutect2, varscan2
- COL5A1 | c.4583G>A p.G1528E | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879320; called by muse, mutect2, varscan2
- COL5A2 | c.4280G>A p.G1427E | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100879896; called by muse, mutect2, varscan2
- COL5A3 | c.3406G>A p.G1136R | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557640184, COSV53408960; called by muse, varscan2
- COL5A3 | c.3364C>T p.R1122C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs764908282, COSV99318015; called by muse, varscan2
- COL7A1 | c.4669G>A p.G1557R | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as CM960406, CS075112, COSV100094641; called by muse, mutect2, varscan2
- COPG2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs782706647, COSV100449543; called by muse, mutect2, varscan2
- COQ8B | c.937G>T p.V313F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs772687976, COSV99699244; called by muse, mutect2, varscan2
- CORIN | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1351801919, COSV99902639; called by muse, mutect2, varscan2
- CPA3 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV99935884; called by muse, mutect2, varscan2
- CPAMD8 | c.1239G>A p.V413= (on ENST00000651564; = p.V366= on NM_015692.5) | Splice Region (SNP) | VAF 26/66 reads (39%) | catalogued as COSV99358838; called by muse, mutect2, varscan2
- CPE | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 53/56 reads (95%) | catalogued as COSV101291529; called by muse, mutect2, varscan2
- CPED1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100119697; called by muse, mutect2, varscan2
- CPNE6 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); catalogued as rs539888917, COSV53745064; called by muse, mutect2, varscan2
- CPNE6 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.544); catalogued as COSV53742908, COSV53743199; called by muse, mutect2, varscan2
- CPNE9 | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV99807978; called by muse, mutect2, varscan2
- CR1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as COSV100887298; called by muse, mutect2, varscan2
- CRB1 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV66331903; called by muse, varscan2
- CREBBP | c.3946G>A p.G1316S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs776643295, COSV99268174; called by muse, mutect2, varscan2
- CREG2 | c.635A>C p.D212A | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240274; called by muse, mutect2, varscan2
- CRISP2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59253803; called by muse, mutect2, varscan2
- CRPPA | c.845C>T p.S282F (on ENST00000407010 / NM_001368197.1; = p.S232F on NM_001101417.4) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1187330759, COSV67907310; called by muse, mutect2
- CRYBG1 | c.3336A>G p.I1112M | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100954344; called by muse, mutect2, varscan2
- CRYBG1 | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV64815014; called by muse, mutect2, varscan2
- CSF2RA | c.413G>A p.W138* | Nonsense Mutation (SNP) | VAF 118/245 reads (48%) | catalogued as COSV100817377; called by muse, mutect2, varscan2
- CSF2RB | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99453111; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1002T>A p.F334L | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174387, COSV59975334; called by muse, mutect2, varscan2
- CSMD3 | c.10390C>T p.P3464S (on ENST00000297405 / NM_001363185.1; = p.P3295S on NM_052900.3) | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141126792, COSV52122184; called by muse, mutect2, varscan2
- CSMD3 | c.1235A>C p.K412T | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as COSV52269679, COSV99821030, COSV99835759; called by muse, mutect2, varscan2
- CSN1S1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.32); catalogued as rs1433960417, COSV99886415; called by muse, mutect2, varscan2
- CSPG4 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs1417856461, COSV100413209; called by muse, mutect2, varscan2
- CSPP1 | c.2665C>T p.P889S (on ENST00000676605; = p.P848S on NM_024790.6) | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV99137935; called by muse, mutect2, varscan2
- CSRP3 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as COSV99788112; called by muse, mutect2, varscan2
- CSTL1 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55678855; called by muse, mutect2, varscan2
- CTNNA2 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV58142015, COSV58183615; called by muse, mutect2, varscan2
- CTNNA3 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 35/59 reads (59%) | catalogued as COSV100373156; called by muse, mutect2, varscan2
- CTR9 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV63728271; called by muse, mutect2, varscan2
- CTR9 | c.2373-1G>A p.X791_splice | Splice Site (SNP) | VAF 52/112 reads (46%) | catalogued as COSV100797216; called by muse, mutect2, varscan2
- CTTNBP2 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99352703; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as rs1557899920, COSV99599685; called by muse, mutect2, varscan2
- CUBN | c.4586C>T p.P1529L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs1251118545, COSV64721597; called by muse, mutect2, varscan2
- CUL5 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 38/40 reads (95%) | catalogued as rs138143013; called by muse, mutect2, varscan2
- CUX2 | c.2925G>A p.Q975= | Splice Region (SNP) | VAF 13/19 reads (68%) | catalogued as rs1336414456, COSV99918288; called by muse, mutect2, varscan2
- CUZD1 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 56/181 reads (31%) | catalogued as rs1343804931, COSV100158520; called by muse, mutect2, varscan2
- CXADR | c.365T>G p.V122G | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99514910; called by muse, mutect2, varscan2
- CXCL16 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53411223, COSV99543371; called by muse, mutect2
- CXCR2 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 96/189 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV100578750; called by muse, mutect2, varscan2
- CYLC2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66336428; called by muse, mutect2, varscan2
- CYP11B1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV99454316; called by muse, mutect2, varscan2
- CYP17A1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773278607, CM090462, COSV100882065; called by muse, mutect2, varscan2
- CYP2C18 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53671156; called by muse, mutect2, varscan2
- CYP2C18 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 101/186 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99608113; called by muse, mutect2, varscan2
- CYP2C19 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs867067400, COSV64907708; called by muse, mutect2, varscan2
- CYP2E1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV99428749; called by muse, mutect2, varscan2
- CYP2F1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 137/321 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406970357, COSV100462465; called by muse, mutect2, varscan2
- CYP3A4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV100315346; called by muse, mutect2, varscan2
- CYP3A7 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV60480567; called by muse, mutect2, varscan2
- CYP4A22 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 94/96 reads (98%) | catalogued as COSV99594519; called by muse, mutect2, varscan2
- CYP4F11 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99930471; called by muse, varscan2
- CYTH4 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50633938; called by muse, mutect2, varscan2
- DAZL | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51713523, COSV99167547; called by muse, mutect2, varscan2
- DCDC1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100662504; called by muse, mutect2, varscan2
- DCDC2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 140/426 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs781230955, COSV65828654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 87/96 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DDX19A | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 115/227 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100156094; called by muse, mutect2, varscan2
- DDX23 | c.2342A>C p.Q781P | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99974577; called by muse, mutect2, varscan2
- DDX31 | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 68/117 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV100936544; called by muse, mutect2, varscan2
- DDX39B | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV100385315; called by muse, mutect2, varscan2
- DDX42 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as rs774201761, COSV63791385; called by muse, mutect2, varscan2
- DDX60L | c.1190G>A p.W397* | Nonsense Mutation (SNP) | VAF 53/58 reads (91%) | catalogued as rs548666335, COSV99486733; called by muse, mutect2, varscan2
- DEF6 | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100359096; called by muse, mutect2, varscan2
- DEFA4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52404417, COSV99857608; called by muse, mutect2, varscan2
- DEFB116 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460804408, COSV101269195; called by muse, mutect2, varscan2
- DENND3 | c.2467-1G>A p.X823_splice | Splice Site (SNP) | VAF 55/96 reads (57%) | catalogued as COSV99370162; called by muse, mutect2, varscan2
- DGCR8 | c.2238G>A p.R746= | Splice Region (SNP) | VAF 23/51 reads (45%) | catalogued as rs376922099; called by muse, mutect2, varscan2
- DGKE | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99400621; called by muse, mutect2, varscan2
- DHX16 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 53/148 reads (36%) | catalogued as COSV100905108; called by muse, mutect2, varscan2
- DHX34 | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV100169129; called by muse, mutect2, varscan2
- DHX8 | c.3106C>T p.H1036Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV99291809; called by muse, mutect2, varscan2
- DIP2C | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs748682540, COSV99789558; called by muse, mutect2, varscan2
- DLGAP2 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as rs762248808, COSV101420968; called by muse, mutect2, varscan2
- DMD | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as CM1212614, CX132480, COSV55883661; called by muse, mutect2, varscan2
- DMGDH | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as COSV54860991, COSV99668285; called by muse, mutect2, varscan2
- DMRT3 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated (0.54); PolyPhen benign (0.2); catalogued as COSV99505602; called by muse, mutect2, varscan2
- DMXL2 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143486672, COSV51843689; called by muse, mutect2, varscan2
- DNAH10 | c.5221G>A p.V1741M (on ENST00000409039; = p.V1680M on NM_207437.3) | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.187); catalogued as COSV101291862; called by muse, mutect2, varscan2
- DNAH10 | c.5455G>A p.G1819S (on ENST00000409039; = p.G1758S on NM_207437.3) | Missense Mutation (SNP) | VAF 128/228 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101291863; called by muse, mutect2, varscan2
- DNAH10 | c.7819G>A p.E2607K (on ENST00000409039; = p.E2546K on NM_207437.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV69003229; called by muse, mutect2, varscan2
- DNAH10 | c.10518G>A p.W3506* (on ENST00000409039; = p.W3445* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | catalogued as rs1236676384, COSV101291865; called by muse, mutect2, varscan2
- DNAH11 | c.7700G>A p.G2567E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746294001, COSV60965732; called by muse, mutect2, varscan2
- DNAH2 | c.2927G>C p.R976P | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101208934, COSV66718149; called by muse, mutect2, varscan2
- DNAH3 | c.4939C>T p.P1647S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99764303; called by muse, mutect2, varscan2
- DNAH3 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as rs769475006, COSV99764307; called by muse, varscan2
- DNAH3 | c.2634G>C p.E878D | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV54556128, COSV99764311; called by muse, varscan2
- DNAH5 | c.6628C>T p.P2210S | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759065820, COSV99443507; called by muse, mutect2, varscan2
- DNAH5 | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 45/51 reads (88%) | catalogued as COSV99443514; called by muse, mutect2, varscan2
- DNAH7 | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs13034775; called by muse, varscan2
- DNAH7 | c.5590G>A p.D1864N | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV56775543; called by muse, varscan2
- DNAH8 | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs200947240, COSV100542713, COSV100542936; called by muse, mutect2, varscan2
- DNAH8 | c.3901G>A p.G1301R | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV100542716; called by muse, mutect2, varscan2
- DNAH8 | c.5578G>A p.G1860R | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59483730; called by muse, mutect2, varscan2
- DNAH8 | c.10755G>A p.M3585I | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.123); catalogued as rs1446924185, COSV100542723; called by muse, mutect2, varscan2
- DNAH9 | c.5701G>A p.D1901N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52380702, COSV99303159; called by muse, mutect2, varscan2
- DNAJB13 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs570872879, COSV100334405; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2, varscan2
- DNHD1 | c.12626T>G p.L4209R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99599249; called by muse, mutect2, varscan2
- DNM1L | c.1994+2T>C p.X665_splice (on ENST00000549701 / NM_012062.5; = p.X628_splice on NM_005690.4) | Splice Site (SNP) | VAF 31/61 reads (51%) | catalogued as COSV99845654; called by muse, mutect2, varscan2
- DNM2 | c.2596C>T p.P866S (on ENST00000355667 / NM_001005360.3; = p.P862S on NM_004945.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); catalogued as rs1242764198, COSV99283989; called by muse, mutect2, varscan2
- DNM3 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754268755, COSV62468632; called by muse, mutect2, varscan2
- DOCK2 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56960620, COSV56994482; called by muse, mutect2
- DOCK4 | c.4715T>C p.L1572P | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301351107, COSV101447735; called by muse, mutect2, varscan2
- DOCK5 | c.5186T>G p.I1729S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV99375791; called by muse, mutect2, varscan2
- DOK1 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs139592271; called by muse, mutect2, varscan2
- DOK3 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs771374795, COSV100394149; called by muse, varscan2
- DPPA2 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101524727; called by muse, mutect2, varscan2
- DPY19L2 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 55/60 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100192599; called by muse, mutect2, varscan2
- DSCAM | c.5707C>T p.P1903S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.994); catalogued as COSV68032875; called by muse, mutect2, varscan2
- DSCAM | c.4178C>T p.S1393F | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV68025204; called by muse, mutect2, varscan2
- DSE | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 51/106 reads (48%) | catalogued as COSV100528242; called by muse, mutect2, varscan2
- DSG1 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 76/84 reads (90%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as rs368044134; called by muse, mutect2, varscan2
- DTX4 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1355772961, COSV99914871; called by mutect2, varscan2
- DVL1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100229175; called by muse, mutect2, varscan2
- DYNC1H1 | c.7868C>T p.S2623F | Missense Mutation (SNP) | VAF 75/83 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794181; called by muse, mutect2, varscan2
- DYNC2H1 | c.12328G>A p.E4110K | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as rs1156534576, COSV100517120; called by muse, mutect2, varscan2
- DYRK4 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99155226; called by muse, mutect2, varscan2
- DZIP1L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as COSV100551024; called by muse, mutect2, varscan2
- EARS2 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101492138; called by muse, mutect2, varscan2
- EBF1 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290415631, COSV100564951; called by muse, mutect2, varscan2
- ECM2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 120/189 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV100755757; called by muse, mutect2, varscan2
- EEF1G | c.174C>T p.V58= | Splice Region (SNP) | VAF 3/8 reads (38%) | catalogued as COSV100239989; called by muse, mutect2
- EEF2K | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99532430; called by muse, mutect2, varscan2
- EFCAB12 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100394407; called by muse, mutect2, varscan2
- EFHD1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs11550700, COSV51132345, COSV51133914; called by muse, mutect2, varscan2
- EFNB3 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs1205148137, COSV99872550; called by muse, mutect2, varscan2
- EGF | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 99/108 reads (92%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs1339389920, COSV54479140; called by muse, mutect2, varscan2
- EGF | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 58/61 reads (95%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54485841, COSV99490313; called by muse, mutect2, varscan2
- EGFL6 | c.1526A>T p.Y509F | Missense Mutation (SNP) | VAF 75/76 reads (99%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV100789822, COSV63634642; called by muse, mutect2, varscan2
- EGFR | c.3538G>T p.E1180* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99285707; called by muse, mutect2, varscan2
- EHD3 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs765964312, COSV59029178; called by muse, mutect2, varscan2
- EHHADH | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 122/211 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV99213085; called by muse, mutect2, varscan2
- EIF1AD | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV100381320; called by muse, mutect2, varscan2
- EIF2AK3 | c.2324C>T p.T775I | Missense Mutation (SNP) | VAF 142/291 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100303291; called by muse, varscan2
- EIF3B | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV62803157; called by muse, mutect2, varscan2
- ELAPOR2 | c.2792G>A p.G931E (on ENST00000450689 / NM_001142749.3; = p.G764E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1223771942, COSV99787969; called by muse, mutect2, varscan2
- ELF3 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs764832150, COSV100668579; called by muse, mutect2, varscan2
- ELP1 | c.3424C>T p.R1142* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as rs768015419, COSV65898615; called by muse, mutect2, varscan2
- EMB | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs893442296, COSV100296548; called by muse, mutect2, varscan2
- EMILIN2 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99598010; called by muse, mutect2, varscan2
- EMILIN2 | c.2823C>T p.T941= | Splice Region (SNP) | VAF 30/33 reads (91%) | catalogued as rs538401222, COSV99598012, COSV99598490; called by muse, mutect2, varscan2
- ENPEP | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV104371909, COSV54447414; called by muse, mutect2, varscan2
- EP300 | c.6319C>T p.P2107S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99607025; called by muse, mutect2, varscan2
- EP300 | c.6437C>T p.P2146L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs745528077, COSV99607026; called by muse, mutect2, varscan2
- EPB41L1 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99148741; called by muse, mutect2, varscan2
- EPB41L4B | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as rs779459216, COSV101000818; called by muse, mutect2, varscan2
- EPB41L5 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99758174; called by muse, mutect2, varscan2
- EPG5 | c.1238A>T p.H413L | Missense Mutation (SNP) | VAF 56/57 reads (98%) | SIFT tolerated (0.51); PolyPhen benign (0.036); catalogued as COSV99956240; called by muse, mutect2, varscan2
- EPHA2 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 60/61 reads (98%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100625986; called by muse, mutect2, varscan2
- EPHA3 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756739935, COSV60693553; called by muse, mutect2, varscan2
- EPHA7 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1179394255, COSV65181436; called by muse, mutect2, varscan2
- ERBB2 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506238; called by muse, mutect2, varscan2
- ERC2 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs757289425, COSV55604382; called by muse, mutect2, varscan2
- ERN1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV70500344; called by muse, mutect2, varscan2
- EXD2 | c.578C>A p.A193D (on ENST00000312994 / NM_001193362.1; = p.A68D on NM_018199.3) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100473584; called by muse, mutect2, varscan2
- EXOSC7 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99651762, COSV99651804; called by muse, mutect2, varscan2
- EXT1 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs773877597, COSV100983539; called by muse, mutect2, varscan2
- EYA1 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs868681957, COSV100378292; called by muse, mutect2, varscan2
- EYA1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV58164905, COSV58167886; called by muse, mutect2, varscan2
- EYA4 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV100765068; called by muse, mutect2, varscan2
- EYA4 | c.581-1G>A p.X194_splice | Splice Site (SNP) | VAF 42/71 reads (59%) | catalogued as COSV100765069, COSV62058516; called by muse, mutect2, varscan2
- FAAH2 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as COSV100887090; called by muse, mutect2, varscan2
- FAM120C | c.3056C>T p.S1019F | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); catalogued as COSV100069466; called by muse, mutect2, varscan2
- FAM153B | c.1105C>T p.P369S (on ENST00000253490; = p.P292S on NM_001265615.1) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV99498679; called by mutect2, varscan2
- FAM193A | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100218411; called by muse, mutect2, varscan2
- FAM221B | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs267602231, COSV100941219; called by muse, mutect2, varscan2
- FAM241B | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 68/106 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100958367; called by muse, mutect2, varscan2
- FAM47A | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60494091; called by muse, mutect2, varscan2
- FAM9A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 141/143 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101121296; called by muse, mutect2, varscan2
- FARP1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60333816; called by muse, mutect2, varscan2
- FASTKD2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 66/134 reads (49%) | catalogued as COSV99378744; called by muse, mutect2, varscan2
- FASTKD2 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV99378748; called by muse, mutect2, varscan2
- FBF1 | c.3191C>T p.S1064F (on ENST00000586717; = p.S1079F on NM_001319193.1) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.785); catalogued as rs1470947396, COSV100044643; called by muse, mutect2
- FBN3 | c.6620-1G>C p.X2207_splice | Splice Site (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99559352; called by muse, mutect2, varscan2
- FBXL19 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs746760154, COSV57943434; called by muse, mutect2, varscan2
- FBXW4 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 90/142 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV100489316; called by muse, varscan2
- FERMT1 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99450875; called by muse, mutect2, varscan2
- FGD2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51462303; called by muse, mutect2, varscan2
- FGF10 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 94/101 reads (93%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.773); catalogued as COSV52936025, COSV99239955; called by muse, mutect2, varscan2
- FGF12 | c.557G>A p.G186E (on ENST00000454309 / NM_021032.5; = p.G124E on NM_004113.6) | Missense Mutation (SNP) | VAF 111/171 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267599732, COSV99277944; called by muse, mutect2, varscan2
- FKBPL | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100913527; called by muse, mutect2, varscan2
- FLG | c.8207G>A p.G2736E | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.841); catalogued as rs775902916, COSV100910313; called by muse, mutect2, varscan2
- FLG | c.5518G>A p.G1840R | Missense Mutation (SNP) | VAF 248/827 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV100910314, COSV64245233; called by muse, mutect2, varscan2
- FLNA | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1441688181, COSV100774224; called by muse, mutect2, varscan2
- FLNC | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100367486; called by muse, mutect2, varscan2
- FLRT2 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100419875; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as rs1336264337, COSV99880491; called by muse, mutect2, varscan2
- FMN2 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100141835, COSV60418128; called by muse, mutect2, varscan2
- FMN2 | c.3650T>A p.I1217N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.403); catalogued as COSV100142036, COSV100142384; called by muse, mutect2, varscan2
- FNDC1 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV51929729, COSV51935656; called by muse, mutect2, varscan2
- FNDC1 | c.2783A>G p.N928S | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV99794596; called by muse, mutect2, varscan2
- FOXRED2 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99340623; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2032T>A p.L678I | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV100435181; called by muse, mutect2, varscan2
- FPR3 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100200509; called by muse, mutect2, varscan2
- FRAS1 | c.123G>A p.W41* | Nonsense Mutation (SNP) | VAF 35/82 reads (43%) | catalogued as COSV99347153; called by muse, mutect2, varscan2
- FRAS1 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as COSV99347163; called by muse, mutect2, varscan2
- FRAS1 | c.7819G>A p.G2607R | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1412856848, COSV99347167; called by muse, mutect2, varscan2
- FREM1 | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs756520564, COSV66518660; called by muse, mutect2, varscan2
- FRMD4A | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV99198371; called by muse, mutect2, varscan2
- FRMD4B | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV101273304; called by muse, mutect2, varscan2
- FRMPD4 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 124/130 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs775114807, COSV101041881; called by muse, mutect2, varscan2
- FSD2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as COSV100574975; called by muse, mutect2, varscan2
- FUT5 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as COSV99398454; called by muse, varscan2
- GABBR2 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99408871; called by muse, mutect2, varscan2
- GABRA1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs775157869, COSV50098608; called by muse, mutect2, varscan2
- GABRA2 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.917); catalogued as COSV62921563; called by muse, mutect2, varscan2
- GABRA6 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs778034380, COSV99194008; called by muse, mutect2, varscan2
- GABRA6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377669113; called by muse, mutect2, varscan2
- GABRB2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.557); catalogued as COSV50903817; called by muse, mutect2, varscan2
- GABRG1 | c.660G>A p.W220* | Nonsense Mutation (SNP) | VAF 39/82 reads (48%) | catalogued as rs267600166, COSV54951101; called by muse, mutect2, varscan2
- GABRG2 | c.1139C>T p.S380F (on ENST00000361925 / NM_001375343.1; = p.S340F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729386, COSV62718810; called by muse, mutect2, varscan2
- GAD2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV99392276; called by muse, mutect2, varscan2
- GADL1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV56977316; called by muse, mutect2, varscan2
- GAL3ST2 | c.30-2A>C p.X10_splice | Splice Site (SNP) | VAF 30/50 reads (60%) | catalogued as COSV99510643; called by muse, mutect2, varscan2
- GALNT13 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV67221429; called by muse, mutect2, varscan2
- GALNT13 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV101221854; called by muse, mutect2, varscan2
- GALNT6 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs866473693, COSV100695258; called by muse, mutect2, varscan2
- GALP | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100627821; called by muse, mutect2, varscan2
- GATA5 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1402045595, COSV53345015, COSV99435562; called by muse, mutect2, varscan2
- GCC1 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.38); catalogued as COSV100365312; called by muse, mutect2, varscan2
- GCM2 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV65275767; called by muse, mutect2, varscan2
- GCN1 | c.3160C>T p.R1054C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs771744883, COSV100324487; called by muse, mutect2, varscan2
- GCNT4 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 103/112 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1339871112, COSV100466220; called by muse, mutect2, varscan2
- GDF3 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100325029; called by muse, mutect2, varscan2
- GEMIN5 | c.1599+1G>A p.X533_splice | Splice Site (SNP) | VAF 38/87 reads (44%) | catalogued as COSV99593509; called by muse, mutect2, varscan2
- GFRA1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100815348; called by muse, mutect2, varscan2
- GFRA2 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV100151303, COSV60777740; called by muse, mutect2, varscan2
- GGA3 | c.499C>T p.P167S (on ENST00000537686 / NM_138619.4; = p.P134S on NM_014001.5) | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as rs1448359663, COSV55457648; called by muse, mutect2, varscan2
- GGT6 | c.800C>T p.S267L (on ENST00000574154 / NM_001122890.3; = p.S235L on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV99625175; called by muse, mutect2, varscan2
- GIGYF2 | c.2479A>G p.R827G | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101003749; called by muse, mutect2, varscan2
- GIMAP8 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV56231157; called by muse, mutect2, varscan2
- GJA10 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs1197566808, COSV65354977, COSV65355951; called by muse, mutect2, varscan2
- GLE1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100012246; called by muse, mutect2, varscan2
- GLP2R | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212562471, COSV99301410; called by muse, varscan2
- GLRA1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51021642; called by muse, mutect2, varscan2
- GLT8D2 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.617); catalogued as COSV100673964, COSV62562404; called by muse, mutect2, varscan2
- GLYATL1 | c.871C>T p.Q291* (on ENST00000317391 / NM_001354699.1; = p.Q322* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 49/101 reads (49%) | catalogued as COSV100265068; called by muse, mutect2, varscan2
- GNA14 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100502413; called by muse, mutect2, varscan2
- GNL2 | c.1831C>A p.L611I | Missense Mutation (SNP) | VAF 241/252 reads (96%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV99953395; called by muse, mutect2, varscan2
- GOLGA2 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs1175534438, COSV57851778; called by muse, mutect2, varscan2
- GPANK1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV100788954; called by muse, mutect2, varscan2
- GPAT2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746013914, COSV64002969; called by muse, mutect2, varscan2
- GPC5 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.53); catalogued as COSV65599440, COSV65633589; called by muse, mutect2, varscan2
- GPD2 | c.2087T>C p.V696A | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV100132792; called by muse, mutect2, varscan2
- GPIHBP1 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.341); catalogued as COSV58209522; called by muse, mutect2, varscan2
- GPR139 | c.722G>A p.W241* | Nonsense Mutation (SNP) | VAF 54/105 reads (51%) | catalogued as COSV100429552; called by muse, mutect2, varscan2
- GPR142 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV100170642; called by muse, mutect2, varscan2
- GPR156 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.36); catalogued as rs1280866975, COSV100251050; called by muse, mutect2, varscan2
- GPR161 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 56/150 reads (37%) | catalogued as COSV99606026; called by muse, mutect2, varscan2
- GPR22 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99771086; called by muse, mutect2, varscan2
- GPR25 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs1347972516, COSV100421653; called by muse, mutect2, varscan2
- GPR27 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as COSV99816121; called by mutect2, varscan2
- GRHL1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); catalogued as rs1249475955, COSV61411032; called by muse, mutect2, varscan2
- GRHL2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52556076, COSV99305804, COSV99307899; called by muse, mutect2, varscan2
- GRIA3 | c.2517G>A p.M839I | Missense Mutation (SNP) | VAF 78/81 reads (96%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV99988611; called by muse, mutect2, varscan2
- GRID1 | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.196); catalogued as COSV60042582; called by muse, mutect2
- GRIK2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as rs751842671, COSV100023049, COSV59712400; called by muse, mutect2, varscan2
- GRIN2A | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100407556; called by muse, mutect2, varscan2
- GRIN2B | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.511); catalogued as COSV101662857; called by muse, mutect2, varscan2
- GRIN2C | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53110209; called by muse, mutect2, varscan2
- GRIN3A | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62451684; called by muse, mutect2, varscan2
- GRIP2 | c.1490C>T p.A497V (on ENST00000619221; = p.A400V on NM_001080423.4) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV99816833; called by muse, mutect2, varscan2
- GRK5 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs746911797, COSV64867157; called by muse, mutect2, varscan2
- GRM3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862005; called by muse, mutect2, varscan2
- GRM5 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100549659; called by muse, mutect2, varscan2
- GTF2H1 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99786222; called by muse, mutect2, varscan2
- GTPBP3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100258535; called by muse, mutect2, varscan2
- GUCA1B | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as rs371272764; called by muse, mutect2
- GUCY1B1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100025204; called by muse, mutect2, varscan2
- GXYLT2 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV101274600; called by muse, mutect2, varscan2
- GYPA | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 79/82 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51626824; called by muse, mutect2, varscan2
- H1-2 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as rs370479531, COSV59189555; called by muse, mutect2, varscan2
- H1-5 | c.507G>C p.K169N | Missense Mutation (SNP) | VAF 158/248 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58899367; called by muse, varscan2
- H1-8 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs1455048561, COSV100180330; called by muse, mutect2, varscan2
- H3C3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as rs762724811, COSV100778227; called by muse, mutect2, varscan2
- H6PD | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 98/147 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1275640415, COSV101072401; called by muse, mutect2, varscan2
- H6PD | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs1320112111, COSV101072402; called by muse, mutect2, varscan2
- HAO2 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 63/67 reads (94%) | catalogued as rs587640182, COSV58038394; called by muse, mutect2, varscan2
- HAP1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.921); catalogued as rs1478678716, COSV100169335, COSV100169901; called by muse, mutect2, varscan2
- HBG2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs63751148, CM0910355, COSV57964828; ClinVar: other; called by muse, varscan2
- HEATR1 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 155/333 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100857297; called by muse, mutect2, varscan2
- HECTD4 | c.9206A>T p.N3069I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101106445; called by muse, mutect2, varscan2
- HECW1 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as COSV101222497; called by muse, mutect2, varscan2
- HELB | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 68/156 reads (44%) | catalogued as rs138227394; called by muse, mutect2, varscan2
- HELQ | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV55028285, COSV99787331; called by muse, mutect2, varscan2
- HEPACAM2 | c.703C>T p.P235S (on ENST00000394468 / NM_001039372.4; = p.P223S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.95); catalogued as rs1313659599, COSV100506319; called by muse, mutect2, varscan2
- HHLA2 | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.062); catalogued as COSV99841919; called by muse, mutect2, varscan2
- HIVEP1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV101044457; called by muse, mutect2, varscan2
- HIVEP3 | c.2201A>G p.K734R | Missense Mutation (SNP) | VAF 88/89 reads (99%) | SIFT tolerated (0.39); PolyPhen benign (0.225); catalogued as COSV99911136; called by muse, mutect2, varscan2
- HLF | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 100/199 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99871898; called by muse, mutect2, varscan2
- HMCN1 | c.5875C>T p.R1959C | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs149920975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMGCLL1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs755851859, COSV99231141; called by muse, mutect2, varscan2
- HNF4G | c.763G>A p.D255N (on ENST00000354370 / NM_001330561.2; = p.D302N on NM_004133.5) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs755923251, COSV62965958, COSV62972686; called by muse, mutect2, varscan2
- HNRNPM | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.028); catalogued as rs1431954805, COSV99725111; called by muse, mutect2, varscan2
- HOXA13 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV99763458; called by muse, mutect2
- HRG | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs750074783, COSV99214457; called by muse, mutect2, varscan2
- HRH4 | c.63T>A p.F21L | Missense Mutation (SNP) | VAF 78/82 reads (95%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756709978, COSV56928558, COSV99907648; called by muse, mutect2, varscan2
- HS3ST4 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs1223869400, COSV58806602; called by muse, mutect2, varscan2
- HSPA6 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100553802; called by muse, mutect2, varscan2
- HSPG2 | c.1356G>A p.R452= | Splice Region (SNP) | VAF 67/70 reads (96%) | catalogued as rs150771453; called by muse, mutect2, varscan2
- HTATIP2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs202128953, COSV101346093; called by muse, mutect2, varscan2
- HTR1A | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated (0.43); PolyPhen benign (0.157); catalogued as COSV100108823; called by muse, mutect2, varscan2
- HTR1E | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540839; called by muse, mutect2, varscan2
- HYDIN | c.4910G>C p.G1637A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99991701; called by muse, mutect2, varscan2
- HYDIN | c.4466G>A p.G1489E | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1215269736, COSV101140836; called by muse, mutect2, varscan2
- HYDIN | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.874); catalogued as COSV99861549; called by muse, mutect2, varscan2
- ICE1 | c.6674C>T p.P2225L | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99663324; called by muse, mutect2, varscan2
- IDO1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs370075063, COSV99503510; called by muse, mutect2, varscan2
- IFNA7 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 50/53 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV99497312; called by muse, mutect2, varscan2
- IGF1R | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416018269, COSV51296735; called by muse, mutect2, varscan2
- IGF2BP1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs267604937, COSV99288128; called by muse, mutect2, varscan2
- IGLON5 | c.498G>A p.W166* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV54538794; called by muse, mutect2, varscan2
- IGLV3-1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs561948127; called by muse, mutect2, varscan2
- IGSF10 | c.5390C>T p.A1797V | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.89); PolyPhen benign (0.129); catalogued as COSV99176532; called by muse, mutect2, varscan2
- IGSF21 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs1324415465, COSV99243346; called by muse, mutect2, varscan2
- IKZF1 | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100497818; called by muse, mutect2, varscan2
- IKZF3 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.926); catalogued as COSV53101428; called by muse, mutect2, varscan2
- IKZF4 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV100008817; called by muse, mutect2, varscan2
- IL17RB | c.947-1G>C p.X316_splice | Splice Site (SNP) | VAF 67/137 reads (49%) | catalogued as COSV99213485; called by muse, mutect2, varscan2
- IL18R1 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1229811049, COSV99294825; called by muse, mutect2, varscan2
- IL1F10 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs774451937, COSV100520079; called by muse, mutect2, varscan2
- IL1RAPL1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 50/53 reads (94%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV100144557, COSV56239502; called by muse, mutect2, varscan2
- IL1RAPL1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 45/46 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56244804, COSV56262199, COSV56277180; called by muse, mutect2, varscan2
- IL21 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 47/48 reads (98%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV52646444; called by muse, mutect2, varscan2
- IL33 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV67342986; called by muse, mutect2, varscan2
- IL34 | c.204C>A p.Y68* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as rs140472147, COSV99851669; called by muse, mutect2, varscan2
- IL36B | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV99382394; called by muse, mutect2, varscan2
- IMPG1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV100885730; called by muse, mutect2, varscan2
- IMPG1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs1562371855, COSV100885731, COSV64059618; called by muse, mutect2, varscan2
- IMPG1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs147225489; called by muse, mutect2, varscan2
- INHBA | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.132); catalogued as COSV99636970; called by muse, mutect2, varscan2
- INSRR | c.2834G>A p.G945D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs1368159648, COSV100947015; called by muse, mutect2, varscan2
- INTS1 | c.5147C>T p.P1716L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs754368707, COSV101247296; called by muse, mutect2, varscan2
- INTS1 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1414742501, COSV101247298; called by muse, mutect2, varscan2
- INTU | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100080237, COSV100081260; called by muse, mutect2, varscan2
- IP6K3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99539530; called by muse, mutect2, varscan2
- IPP | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 164/339 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as rs1417104157, COSV100739319; called by muse, mutect2, varscan2
- IQCH | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100245251; called by muse, mutect2, varscan2
- IQGAP3 | c.2065C>T p.Q689* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as rs751089181, COSV100752016; called by muse, mutect2, varscan2
- IREB2 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 133/230 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs898859127, COSV51921203, COSV51925705; called by muse, mutect2, varscan2
- IRF2 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV66929277; called by muse, mutect2, varscan2
- IRF2BP2 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as rs1182052495, COSV100784214; called by muse, mutect2, varscan2
- ITGA8 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as COSV100958662, COSV65226930; called by muse, mutect2, varscan2
- ITGB4 | c.5077G>A p.D1693N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as rs142794337; called by muse, mutect2, varscan2
- ITGB7 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1255583010, COSV99913850; called by muse, mutect2, varscan2
- ITPR1 | c.2440G>A p.E814K (on ENST00000354582; = p.E799K on NM_002222.7) | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100228968; called by muse, mutect2, varscan2
- ITPRID2 | c.3508C>T p.P1170S | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs750129010, COSV100237735; called by muse, mutect2, varscan2
- ITPRID2 | c.3509C>T p.P1170L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV100237738; called by muse, mutect2, varscan2
- IZUMO1R | c.674C>T p.S225F (on ENST00000440961; = p.S232F on NM_001199206.3) | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1283107964, COSV100126777; called by muse, mutect2, varscan2
- KAT5 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV100383773; called by muse, mutect2, varscan2
- KCNG1 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as rs758172905, COSV100856938; called by muse, mutect2, varscan2
- KCNH1 | c.1921G>A p.G641R (on ENST00000271751 / NM_172362.3; = p.G614R on NM_002238.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55103315; called by muse, mutect2, varscan2
- KCNH5 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100524940; called by muse, mutect2, varscan2
- KCNK9 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs1237927464, COSV57278660; called by muse, mutect2, varscan2
- KCNMA1 | c.2680C>T p.H894Y (on ENST00000286628 / NM_001161352.2; = p.H836Y on NM_002247.4) | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99694238; called by muse, mutect2, varscan2
- KCNS1 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100066944; called by muse, mutect2, varscan2
- KCNT1 | c.1117G>A p.E373K (on ENST00000488444; = p.E392K on NM_020822.3) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs780708628, COSV53698685; ClinVar: uncertain significance; called by muse, varscan2
- KCNT2 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1456007659, COSV54071211; called by muse, mutect2, varscan2
- KDM1A | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100752270; called by muse, mutect2, varscan2
- KDM2A | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101284572; called by muse, mutect2, varscan2
- KDR | c.3998G>A p.G1333E | Missense Mutation (SNP) | VAF 127/268 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55757841, COSV55774004; called by muse, mutect2, varscan2
- KDR | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs775179342, COSV55763932, COSV99816436; called by muse, mutect2, varscan2
- KEL | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.412); catalogued as COSV100786808; called by muse, mutect2, varscan2
- KHDC3L | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64868860; called by muse, mutect2, varscan2
- KHDC4 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 138/247 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs760168909, COSV100850749, COSV64164546; called by muse, varscan2
- KIAA0408 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV64108884; called by muse, mutect2, varscan2
- KIAA1217 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285994, COSV100287092; called by muse, mutect2, varscan2
- KIAA2013 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 47/48 reads (98%) | catalogued as rs768845393, COSV100927105; called by muse, mutect2, varscan2
- KIF1A | c.2063A>G p.E688G | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.35); catalogued as COSV100239486; called by muse, mutect2, varscan2
- KIF1B | c.2095C>T p.L699F (on ENST00000377086 / NM_001365952.1; = p.L653F on NM_015074.3) | Missense Mutation (SNP) | VAF 183/187 reads (98%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV55815913, COSV99822858; called by muse, mutect2, varscan2
- KIF20B | c.3571G>A p.E1191K (on ENST00000371728 / NM_001284259.2; = p.E1151K on NM_016195.4) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV99589308; called by muse, mutect2, varscan2
- KIF21B | c.3133G>A p.G1045R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs774676250, COSV100143250; called by muse, mutect2, varscan2
- KIF21B | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766937251, COSV100143254; called by muse, mutect2, varscan2
- KIF4B | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101469147; called by muse, mutect2, varscan2
- KLHL11 | c.1913G>A p.R638K | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100044129; called by muse, mutect2, varscan2
- KLHL14 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT tolerated (1); PolyPhen possibly damaging (0.672); catalogued as COSV100808546; called by muse, mutect2, varscan2
- KLHL2 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 194/208 reads (93%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV99899501; called by muse, mutect2, varscan2
- KLHL38 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs375302916; called by muse, mutect2, varscan2
- KLHL40 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99825278; called by muse, mutect2, varscan2
- KLHL8 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911181; called by muse, mutect2, varscan2
- KLK12 | c.597T>A p.D199E | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141756; called by muse, mutect2, varscan2
- KLK2 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as rs774136702, COSV100319788; called by muse, mutect2, varscan2
- KLRC1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs369792162, COSV61724885; called by muse, mutect2, varscan2
- KLRK1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV99554967; called by muse, mutect2, varscan2
- KMT2B | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99718620; called by muse, mutect2, varscan2
- KRI1 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100469615; called by muse, mutect2, varscan2
- KRIT1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100388553; called by muse, mutect2, varscan2
- KRT1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV99358427; called by muse, mutect2
- KRT27 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56971284; called by muse, mutect2, varscan2
- KRT31 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs1477546834, COSV99289290; called by muse, mutect2, varscan2
- KRTAP24-1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.875); catalogued as rs760808152, COSV100447278; called by muse, mutect2, varscan2
- KRTAP4-2 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs413682, COSV100894503; called by muse, mutect2, varscan2
- KRTAP5-10 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV64796068; called by muse, mutect2, varscan2
- LAMA4 | c.2296C>T p.L766F (on ENST00000230538 / NM_001105206.3; = p.L759F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV100037385; called by muse, mutect2, varscan2
- LAMA5 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs193920947, COSV53352514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB1 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV55961466, COSV55964222; called by muse, mutect2, varscan2
- LAMB3 | c.1895A>T p.E632V | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100620021; called by muse, mutect2, varscan2
- LAP3 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1305030451, COSV99883956; called by muse, mutect2, varscan2
- LATS1 | c.2983C>T p.R995C | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53587210, COSV99486386; called by muse, mutect2, varscan2
- LCE5A | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.125); catalogued as rs1557942602, COSV100524127; called by muse, mutect2, varscan2
- LCOR | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as rs768032236, COSV53714809; called by muse, mutect2, varscan2
- LETMD1 | c.749A>G p.Q250R | Missense Mutation (SNP) | VAF 79/89 reads (89%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs554146914, COSV99950211; called by muse, mutect2, varscan2
- LGALS14 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as COSV100648383; called by muse, mutect2
- LGALS9B | c.878G>A p.R293Q (on ENST00000423676 / NM_001367292.1; = p.R292Q on NM_001042685.2) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs143077736, COSV60864621; called by muse, mutect2, varscan2
- LGALS9C | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs768573755, COSV100055450; called by muse, varscan2
- LGMN | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1200211407, COSV100605669; called by muse, mutect2, varscan2
- LHX4 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99761070; called by muse, mutect2, varscan2
- LILRA1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as rs530732441, COSV52182590; called by muse, varscan2
- LILRA4 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs754460298, COSV99392791; called by muse, mutect2
- LILRB2 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100078854; called by muse, mutect2, varscan2
- LIPH | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as COSV99955696; called by muse, mutect2, varscan2
- LIPH | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 104/173 reads (60%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99955697; called by muse, mutect2, varscan2
- LIPI | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV60711512; called by muse, mutect2, varscan2
- LNX2 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100310397; called by muse, mutect2, varscan2
- LONRF1 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.666); catalogued as rs1372914003, COSV101238157; called by muse, mutect2, varscan2
- LOXL4 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.183); catalogued as rs1303064346, COSV99583523; called by muse, mutect2, varscan2
- LPAR2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs755613652, COSV101345476; called by muse, mutect2, varscan2
- LPAR5 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100320879; called by muse, mutect2, varscan2
- LPO | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV99228214; called by muse, varscan2
- LRIT1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1173748005, COSV64512960; called by muse, mutect2, varscan2
- LRP1B | c.11620C>T p.Q3874* | Nonsense Mutation (SNP) | VAF 46/105 reads (44%) | catalogued as COSV67213919; called by muse, mutect2, varscan2
- LRP1B | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1396508579, COSV101250052; called by muse, mutect2, varscan2
- LRRC18 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.525); catalogued as COSV99628127, COSV99631025; called by muse, mutect2, varscan2
- LRRC49 | c.223T>A p.L75M | Missense Mutation (SNP) | VAF 119/198 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99536783; called by muse, mutect2, varscan2
- LRRC49 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 134/197 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757049481, COSV53017295; called by muse, mutect2, varscan2
- LRRC4C | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs568747706, COSV53425880; called by muse, mutect2, varscan2
- LRRC61 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs969961213, COSV99784514; called by muse, mutect2, varscan2
- LRRIQ3 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 56/60 reads (93%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1296939696, COSV100598566, COSV63048593; called by muse, mutect2, varscan2
- LRSAM1 | c.1756T>C p.Y586H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs1407198507, COSV100030975; called by muse, mutect2, varscan2
- LRTM1 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 63/115 reads (55%) | catalogued as rs532949078, COSV55524497; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV101012169; called by muse, mutect2, varscan2
- LY96 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.161); catalogued as rs1326131150, COSV99514212; called by muse, mutect2, varscan2
- LYN | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV70205430; called by muse, mutect2, varscan2
- MAFA | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100339062; called by muse, mutect2
- MAG | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.479); catalogued as COSV100727515, COSV62700176, COSV62702060; called by muse, mutect2, varscan2
- MAGEA1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 142/146 reads (97%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as rs782053099, COSV100756599; called by muse, mutect2, varscan2
- MAGEC3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs777086857, COSV74217390; called by muse, mutect2, varscan2
- MAGEC3 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 79/82 reads (96%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100024651; called by muse, mutect2, varscan2
- MAGI1 | c.2213G>A p.R738K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV100438895; called by muse, mutect2, varscan2
- MAN1A1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63787171; called by muse, mutect2, varscan2
- MAN2A2 | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV100847709; called by muse, mutect2, varscan2
- MAN2C1 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1185738551, COSV99145168; called by muse, mutect2, varscan2
- MAP2K7 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67609343; called by muse, mutect2, varscan2
- MAP3K3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100675404; called by muse, mutect2, varscan2
- MAP4K4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100153228; called by muse, mutect2, varscan2
- MAPK13 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99274803; called by muse, mutect2, varscan2
- MAPT | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.671); catalogued as COSV99289541; called by muse, mutect2, varscan2
- MAST2 | c.1930A>T p.T644S | Missense Mutation (SNP) | VAF 90/93 reads (97%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100787759; called by muse, mutect2, varscan2
- MAST2 | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 92/95 reads (97%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs905996017, COSV100787760; called by muse, mutect2, varscan2
- MAST3 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1376711309, COSV99444062; called by muse, mutect2
- MBOAT2 | c.876G>T p.W292C | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100019604, COSV60010681; called by muse, mutect2, varscan2
- MCHR1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99967701; called by muse, mutect2, varscan2
- MCM10 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV101097811; called by muse, mutect2, varscan2
1,647 further variants in this file (830 protein-altering or splice-affecting, 764 silent, 53 other) are not listed here.
